Gene-level copy-number profile of tumor specimen TCGA-BI-A0VS-01A from TCGA case TCGA-BI-A0VS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 48.8 years (17,839 days).
Specimen TCGA-BI-A0VS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.b71a6f02-3d0e-4dd4-8f33-0f5bb051ebee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BI-A0VS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55e3044c-4e7f-46fa-95ce-4b04b8d4f4cf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 12; copy number 2: 111; copy number 3: 5,530; copy number 4: 25,746; copy number 5: 12,540; copy number 6: 5,748; copy number 7: 2,081; copy number 8: 2,584; copy number 9: 140; copy number 10: 749; copy number 11: 3,188; copy number 12: 469; copy number 13: 583; copy number 14: 63; copy number 15: 56; copy number 16: 52; copy number 19: 120; copy number 35: 1; copy number 37: 3; copy number 66: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BI-A0VS-01A-11D-A10T-01): tumor purity 0.49, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,408 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,698,060–152,813,108, 120 genes, copy number 19 (broad region; genes not listed).
- chr3:119,294,383–198,222,513, 1,464 genes, copy number 11–15 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr6:58,386,799–65,707,226, 39 genes, copy number 10 (within-gene range 4–10): AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr8:35,080,592–39,580,134, 93 genes, copy number 9 (broad region; genes not listed).
- chr8:40,900,016–145,066,685, 1,616 genes, copy number 11 (broad region; genes not listed).
- chr12:22,625,075–26,079,892, 47 genes, copy number 14–66 (within-gene range 4–66): ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8.
- chr14:22,197,446–22,482,959, 1 gene, copy number 11 (within-gene range 6–11): AC244502.1.
- chr14:22,221,896–22,530,378, 67 genes, copy number 11 (broad region; genes not listed).
- chr14:77,098,311–77,259,495, 2 genes, copy number 9 (within-gene range 8–9): AC007375.2, TMEM63C.
- chr14:77,173,075–79,868,291, 34 genes, copy number 9 (within-gene range 8–9): FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA, FXNP1, NRXN3, RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1, AC026888.1.
- chr18:77,108,284–77,863,567, 11 genes, copy number 9: AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461.
- chr20:30,484,925–36,528,637, 204 genes, copy number 11–16 (within-gene range 8–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
